Somatic mutation profile of tumor specimen MMRF_2301_1_BM_CD138pos (aliquot MMRF_2301_1_BM_CD138pos_T1_KHS5U_L11012) from MMRF case MMRF_2301, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.1 years (22,681 days).
Specimen MMRF_2301_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd08463-f90b-490e-9551-1d52e64d82a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2301_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2301_1_PB_Whole_C2_KHS5U_L11013; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4fb4e77-99e6-46f7-8ae6-8c51d311b4ed

The open-access MAF lists 84 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 21, Silent 7, Intron 5, 5'UTR 4, 5'Flank 3, Frame Shift Del 1, In Frame Del 1, Splice Region 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 42/64 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs772102642, COSV52190603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD18A | c.2029A>G p.R677G | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1426603915; called by muse, mutect2, varscan2
- CCDC91 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs753292484, COSV60339547; called by muse, mutect2, varscan2
- CLCN7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 33/35 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs775186615; called by muse, mutect2, varscan2
- DHX32 | c.1188_1190del p.S397del | In Frame Del (DEL) | VAF 129/296 reads (44%) | catalogued as rs766010296; called by pindel, varscan2
- H1-4 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1387610611, COSV56800081, COSV99175236; called by muse, mutect2, varscan2
- IGHD1-20 | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 13/13 reads (100%) | PolyPhen possibly damaging (0.817); catalogued as rs377487993; called by muse, varscan2
- IGHV2-5 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 92/108 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs1065551; called by muse, varscan2
- IGHV2-70 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs375052259; called by muse, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, mutect2
- IGKJ3 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 60/340 reads (18%) | catalogued as rs375607256; called by muse, mutect2
- MUCL3 | c.1423C>T p.R475W (on ENST00000304311; = p.R1351W on NM_080870.4) | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1469903632; called by muse, mutect2, varscan2
- TMEM168 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.83); catalogued as rs752161781, COSV57180669; called by muse, mutect2, varscan2
- UNC13B | c.825T>G p.S275R | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1445854429; called by muse, mutect2, varscan2
- BOP1 | c.782A>T p.H261L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CACNA2D2 | c.1958T>G p.L653R | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CDH13 | c.1721C>T p.T574I | Missense Mutation (SNP) | VAF 107/217 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- CLTC | c.4471G>A p.D1491N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- DEPDC5 | c.1496A>G p.D499G | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EEPD1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FUT9 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- H1-2 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IGHV2-5 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, varscan2
- IGHV2-70D | c.220T>A p.W74R | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); called by muse, varscan2
- IGHV2-70D | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.189); called by muse, varscan2
- IL1R1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ITCH | c.1822A>G p.M608V (on ENST00000262650 / NM_001257137.3; = p.M567V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KLHDC7B | c.494C>T p.P165L (on ENST00000395676; = p.P806L on NM_138433.5) | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LRP2 | c.5099C>T p.S1700F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MYOM3 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PCDHGB1 | c.465A>C p.Q155H | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLA2 | c.111T>G p.N37K | Missense Mutation (SNP) | VAF 269/422 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, varscan2
- POLA2 | c.195T>A p.F65L | Missense Mutation (SNP) | VAF 167/249 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.302); called by muse, varscan2
- ROBO3 | c.2987-3C>A | Splice Region (SNP) | VAF 105/344 reads (31%) | called by muse, mutect2, varscan2
- RP1 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SGCB | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC33A1 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 101/174 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SNX25 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SORCS1 | c.3194A>G p.N1065S | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 56/77 reads (73%) | called by mutect2, pindel, varscan2
- UTP15 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZDHHC13 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- FBXO31 | c.813G>A p.L271= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs765421054; called by muse, varscan2
- IGKJ3 | c.9T>C p.T3= | Silent (SNP) | VAF 60/336 reads (18%) | catalogued as rs538609342; called by muse, mutect2
- OGT | c.930T>A p.A310= | Silent (SNP) | VAF 62/65 reads (95%) | called by muse, mutect2, varscan2
- QSOX1 | c.234G>T p.P78= | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- RYR1 | c.10758C>T p.A3586= | Silent (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- SPATA18 | c.627G>A p.E209= | Silent (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2
- SVEP1 | c.5733A>T p.I1911= | Silent (SNP) | VAF 97/314 reads (31%) | catalogued as rs780709478; called by muse, mutect2, varscan2
- AC005324.2 | c.*1865C>T | 3'UTR (SNP) | VAF 201/394 reads (51%) | called by muse, mutect2, varscan2
- ARMC5 | chr16:31458564 T>C | 5'Flank (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- BRD1 | c.2360-165C>T | Intron (SNP) | VAF 67/135 reads (50%) | catalogued as rs1021297717; called by muse, mutect2, varscan2
- C6 | c.*459G>T | 3'UTR (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- C9orf57 | c.*496dup | 3'UTR (INS) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- CIAO2A | c.385+334T>C | Intron (SNP) | VAF 13/216 reads (6%) | catalogued as rs768020465; called by muse, mutect2
- CLCN4 | c.*2804T>C | 3'UTR (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- CUL5 | c.*727del | 3'UTR (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.*595G>T | 3'UTR (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.*3163C>A | 3'UTR (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- FGF1 | c.*2616A>G | 3'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- FIGN | c.*2520del | 3'UTR (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- HMGB1 | c.*1454G>A | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- IL21R | c.*1438T>A | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128918240 G>A | 3'Flank (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- LRRTM4 | c.-19C>A | 5'UTR (SNP) | VAF 266/619 reads (43%) | catalogued as rs552901765, COSV101297618; called by muse, mutect2, varscan2
- MDS2 | chr1:23627217 G>A | 5'Flank (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- NKAPD1 | c.*785C>T | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- NUCKS1 | c.*2359T>C | 3'UTR (SNP) | VAF 46/91 reads (51%) | catalogued as rs1050689409; called by muse, mutect2, varscan2
- PDZRN3 | c.-60T>C | 5'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- PLCZ1 | c.1592-1340A>C | Intron (SNP) | VAF 80/187 reads (43%) | called by muse, mutect2, varscan2
- PRKCZ | c.421-73T>C | Intron (SNP) | VAF 24/40 reads (60%) | called by mutect2, varscan2
- PRTFDC1 | c.*458C>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PTH | c.*77A>C | 3'UTR (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- RAX | c.-192G>C | 5'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- RCAN2 | c.-135_-130del | 5'UTR (DEL) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- RNPS1 | chr16:2271865 T>C | 5'Flank (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- RTP5 | c.*386G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- SPOPL | c.*1861T>C | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- TAFA5 | c.113-70182C>A | Intron (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- TPP2 | c.*91del | 3'UTR (DEL) | VAF 46/113 reads (41%) | called by mutect2, pindel, varscan2
- TULP4 | c.*1185T>G | 3'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- VSIR | c.*3360A>G | 3'UTR (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- ZNF516 | c.*2041A>G | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, varscan2
